Somatic mutation profile of tumor specimen TCGA-F7-8298-01A (aliquot TCGA-F7-8298-01A-11D-2394-08) from TCGA case TCGA-F7-8298, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 58.7 years (21,445 days).
Specimen TCGA-F7-8298-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fcc6825-24cd-45d2-820b-d5d11437fa72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F7-8298-10A (Blood Derived Normal), aliquot TCGA-F7-8298-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba300574-dd17-4a4a-9859-9187570e531b

The open-access MAF lists 106 somatic variants for this specimen: 83 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 20, Nonsense Mutation 5, Splice Site 2, Intron 2, Splice Region 1, 3'Flank 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB8 | c.731A>T p.D244V (on ENST00000297504 / NM_001282291.2; = p.D227V on NM_007188.5) | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99874806; called by muse, mutect2, varscan2
- AMFR | c.1378A>G p.M460V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs370219059, COSV51922333; called by muse, mutect2, varscan2
- ARF1 | c.58A>T p.I20F | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.293); catalogued as COSV99683297; called by muse, mutect2, varscan2
- ATG14 | c.689C>A p.T230N | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs1035028440, COSV55957575; called by muse, mutect2, varscan2
- ATG2A | c.5372C>T p.S1791L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV101034669; called by muse, mutect2, varscan2
- BEX2 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV101012839; called by muse, varscan2
- CACNA2D1 | c.93C>T p.V31= | Splice Region (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100667035; called by muse, mutect2, varscan2
- CADPS2 | c.609G>C p.W203C | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100464925; called by muse, mutect2, varscan2
- CARNS1 | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1193611604, COSV100322163; called by muse, mutect2, varscan2
- CASS4 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV100824839, COSV64385596, COSV64387426; called by muse, mutect2, varscan2
- CC2D1A | c.1568A>G p.H523R | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV100528634; called by muse, mutect2, varscan2
- CCDC70 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 79/140 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs61730661; called by muse, mutect2, varscan2
- CEBPD | c.202A>G p.M68V | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99855753; called by muse, mutect2, varscan2
- CHRNA7 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs754418919, COSV60967589; called by muse, mutect2, varscan2
- CRB1 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as COSV100959180; called by muse, mutect2, varscan2
- CSMD3 | c.5605+2T>A p.X1869_splice (on ENST00000297405 / NM_001363185.1; = p.X1765_splice on NM_052900.3) | Splice Site (SNP) | VAF 17/77 reads (22%) | catalogued as COSV52164955, COSV99842920; called by muse, mutect2, varscan2
- CYP27B1 | c.1133T>A p.L378Q | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99141617; called by muse, mutect2, varscan2
- DHCR24 | c.302C>G p.S101* | Nonsense Mutation (SNP) | VAF 57/264 reads (22%) | catalogued as COSV100987835; called by muse, mutect2, varscan2
- DLX5 | c.200G>C p.G67A | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV99756594; called by muse, mutect2, varscan2
- DMD | c.10102G>A p.D3368N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as CM070895, CM140178, COSV100628622; called by muse, mutect2, varscan2
- DNAH8 | c.10066C>G p.L3356V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100546660; called by muse, mutect2, varscan2
- EHBP1 | c.1007C>G p.P336R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99861513; called by muse, mutect2, varscan2
- ELF4 | c.781A>T p.N261Y | Missense Mutation (SNP) | VAF 75/147 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100257528; called by muse, mutect2, varscan2
- EME2 | c.146G>C p.R49T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV99169448; called by muse, mutect2
- FAT3 | c.12887G>T p.R4296L | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.91); catalogued as COSV99968810; called by muse, varscan2
- GBP6 | c.1613G>C p.R538T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as COSV100969627, COSV65010602; called by muse, mutect2, varscan2
- GCNA | c.1928A>G p.H643R | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.14); catalogued as COSV101031706; called by muse, mutect2, varscan2
- GDPGP1 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100292114; called by muse, mutect2, varscan2
- GLIS3 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs759183029, COSV100173446, COSV60938063; called by muse, mutect2, varscan2
- GLRA1 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99199645; called by muse, mutect2, varscan2
- HCN1 | c.2438C>A p.A813D | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.274); catalogued as rs777158203, COSV57494324; called by muse, mutect2, varscan2
- HERC2 | c.10679G>A p.R3560Q | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs779071996, COSV99875825; called by muse, mutect2, varscan2
- IFT122 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56202633, COSV99959668; called by muse, mutect2, varscan2
- IL6R | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs982263084, COSV100690997; called by muse, mutect2, varscan2
- JPH3 | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99413776; called by muse, mutect2, varscan2
- KCTD20 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); catalogued as COSV99536182; called by muse, mutect2, varscan2
- KDM7A | c.171C>G p.I57M | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.365); catalogued as rs753865550, COSV99134908; called by muse, mutect2, varscan2
- KRT5 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1415918495, COSV99358191; called by muse, mutect2, varscan2
- LRP1B | c.5402G>T p.G1801V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV67233969, COSV67250560; called by muse, mutect2, varscan2
- MYOZ2 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as COSV61085033; called by muse, mutect2, varscan2
- NKAIN3 | c.71G>A p.R24K | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs868394164, COSV100131217, COSV100135676; called by muse, varscan2
- NR3C2 | c.2799+1G>A p.X933_splice | Splice Site (SNP) | VAF 22/35 reads (63%) | catalogued as CS070397, COSV60986028; called by muse, mutect2, varscan2
- NT5DC3 | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 37/152 reads (24%) | catalogued as COSV101231014, COSV67321152; called by muse, mutect2, varscan2
- OR11G2 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100640013; called by muse, mutect2, varscan2
- OR2M2 | c.473T>C p.I158T | Missense Mutation (SNP) | VAF 111/277 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs1253413967, COSV100677287; called by muse, mutect2, varscan2
- OSBPL5 | c.607G>C p.G203R | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99720661; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.2510G>A p.R837K (on ENST00000259318 / NM_001136562.3; = p.R1081K on NM_007203.5) | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV99395556; called by muse, mutect2, varscan2
- PCDHA3 | c.510C>A p.Y170* | Nonsense Mutation (SNP) | VAF 34/70 reads (49%) | catalogued as COSV100974087, COSV65369918; called by muse, mutect2, varscan2
- PDGFD | c.1103C>A p.P368Q | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100160260; called by muse, mutect2
- PIGS | c.1381G>A p.V461M | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs114925145, COSV99257164; called by muse, mutect2, varscan2
- POSTN | c.5T>C p.I2T | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV65714100; called by muse, mutect2, varscan2
- PRKAA2 | c.1643C>T p.T548I | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100983006; called by muse, mutect2
- PRRC2A | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1221489101, COSV63224619; called by muse, mutect2
- PUM1 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.984); catalogued as rs539966622, COSV99928698; called by muse, mutect2, varscan2
- RBBP8NL | c.1334C>G p.S445W | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99436881; called by muse, mutect2, varscan2
- RIMS2 | c.3094C>G p.H1032D (on ENST00000666250 / NM_001348490.2; = p.H840D on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.116); catalogued as COSV51706670; called by muse, mutect2, varscan2
- RYR3 | c.2818G>C p.V940L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV101213573; called by muse, mutect2
- SEBOX | c.344C>A p.S115Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.38); catalogued as COSV99412236; called by muse, mutect2, varscan2
- SENP6 | c.1276C>G p.Q426E | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as COSV59189543; called by muse, mutect2, varscan2
- SERINC3 | c.1300C>G p.Q434E | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV99667924; called by muse, mutect2, varscan2
- SERPINI2 | c.202C>A p.Q68K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99248236; called by muse, mutect2, varscan2
- SMYD1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV101352484; called by muse, mutect2
- SNRPA1 | c.228A>G p.I76M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99574661; called by mutect2, varscan2
- SNX27 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100919100, COSV64326999; called by muse, mutect2, varscan2
- SPEF2 | c.2810C>A p.T937N | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.462); catalogued as COSV100608363; called by muse, mutect2
- SPSB3 | c.472C>G p.P158A | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); catalogued as COSV99236643; called by muse, mutect2
- SV2A | c.1408G>C p.D470H | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64964483; called by muse, mutect2
- SYNJ1 | c.1588G>C p.D530H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100449540; called by muse, mutect2, varscan2
- TFG | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV53747006, COSV99561157; called by muse, mutect2, varscan2
- TLR10 | c.522C>G p.F174L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100457904; called by muse, mutect2, varscan2
- TMEM108 | c.886G>T p.G296W | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); catalogued as COSV100419334; called by mutect2, varscan2
- TOM1L2 | c.718G>C p.E240Q (on ENST00000379504 / NM_001350333.2; = p.E190Q on NM_001033551.3) | Missense Mutation (SNP) | VAF 39/196 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58887577; called by muse, mutect2, varscan2
- TP53BP1 | c.5563G>A p.E1855K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV99539317; called by muse, mutect2, varscan2
- UCMA | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs372826471; called by mutect2, varscan2
- WIPF2 | c.212G>C p.S71T | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV100063784; called by muse, mutect2, varscan2
- ZBTB7A | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100475861; called by muse, mutect2, varscan2
- ZNF516 | c.1918G>A p.G640S | Missense Mutation (SNP) | VAF 99/157 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs559748313, COSV71586733; called by muse, mutect2, varscan2
- ZNF556 | c.1004G>C p.R335T | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV100298858; called by muse, mutect2, varscan2
- ZNF556 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV100298860; called by muse, mutect2, varscan2
- ZNF600 | c.377G>T p.R126I | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as COSV57742148, COSV57742425; called by muse, mutect2, varscan2
- MPP5 | c.1778dup p.Y593* | Nonsense Mutation (INS) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- PML | c.686_688del p.I229del | In Frame Del (DEL) | VAF 5/37 reads (14%) | called by mutect2, pindel, varscan2
- TP53 | c.588_612del p.V197Ifs*42 | Frame Shift Del (DEL) | VAF 33/68 reads (49%) | called by mutect2, pindel, varscan2
- AKAP6 | c.3888C>G p.L1296= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV99803166; called by muse, mutect2, varscan2
- B3GNT6 | c.1074C>T p.F358= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs782657432, COSV62829198; called by muse, mutect2, varscan2
- BEX2 | c.276G>A p.V92= | Silent (SNP) | VAF 64/122 reads (52%) | catalogued as COSV101012842; called by muse, varscan2
- CLTC | c.540T>A p.A180= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as COSV99292707; called by muse, mutect2, varscan2
- CSNK2A2 | c.162A>G p.V54= | Silent (SNP) | VAF 47/174 reads (27%) | catalogued as COSV99345390; called by muse, mutect2, varscan2
- FANCG | c.1548C>G p.A516= | Silent (SNP) | VAF 123/173 reads (71%) | catalogued as COSV100734305; called by muse, mutect2, varscan2
- FER1L5 | c.4980T>C p.Y1660= (on ENST00000623019; = p.Y1633= on NM_001293083.2) | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs770082713, COSV101208894; called by muse, mutect2, varscan2
- GNAI2 | c.549G>A p.T183= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as rs1450299309, COSV99807179; called by muse, mutect2, varscan2
- LITAF | c.240C>T p.Y80= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs149184234; ClinVar: likely benign; called by muse, mutect2, varscan2
- NXT2 | c.402C>T p.F134= (on ENST00000372106 / NM_001242617.2; = p.F189= on NM_018698.5) | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV99484181; called by muse, mutect2, varscan2
- ODC1 | c.1086C>T p.G362= | Silent (SNP) | VAF 8/67 reads (12%) | catalogued as rs745558331, COSV99301351; called by muse, mutect2, varscan2
- PCDH8 | c.1242C>G p.V414= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100131944; called by muse, mutect2, varscan2
- PDE8B | c.1347C>T p.I449= | Silent (SNP) | VAF 60/131 reads (46%) | catalogued as rs777128035, COSV99367302; called by muse, mutect2, varscan2
- SEC23IP | c.498A>T p.S166= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV100957026; called by muse, mutect2, varscan2
- SELL | c.567T>C p.N189= (on ENST00000650983; = p.N176= on NM_000655.5) | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs1362742119, COSV99357730; called by muse, mutect2, varscan2
- SORL1 | c.5154A>G p.L1718= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1191927299, COSV99494960; called by muse, mutect2, varscan2
- TBX20 | c.588A>G p.L196= | Silent (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- TFAP2A | c.969C>T p.L323= (on ENST00000482890; = p.L315= on NM_001032280.3) | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as rs1803117, COSV100117105; called by muse, mutect2, varscan2
- TMEM80 | c.225G>C p.L75= (on ENST00000526170 / NM_001276274.1; = p.L137= on NM_174940.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 112/312 reads (36%) | catalogued as COSV101284301; called by muse, mutect2, varscan2
- USP5 | c.1941C>T p.F647= | Silent (SNP) | VAF 43/147 reads (29%) | catalogued as COSV99978947; called by muse, mutect2, varscan2
- DOCK8 | c.53+51G>A | Intron (SNP) | VAF 6/13 reads (46%) | catalogued as COSV101213687; called by muse, varscan2
- DTNA | c.1094+1389C>A | Intron (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99313767; called by muse, mutect2, varscan2
- SECISBP2 | chr9:89363807 G>A | 3'Flank (SNP) | VAF 26/77 reads (34%) | catalogued as rs776947249, COSV100358644; called by muse, mutect2, varscan2
